TCGA case TCGA-20-0990 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Fox Chase Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9524775-6b50-4793-8858-24b6a6d3e4e6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 74.4 years (27,170 days); Year of diagnosis: 2005; Method of diagnosis: Fine Needle Aspiration; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 871 days (2.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 116 days; Days to treatment end: 236 days; Number of cycles: 6; Treatment dose: 480 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 116 days; Days to treatment end: 236 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 901 days (2.5 years); Days to treatment end: 999 days (2.7 years); Number of cycles: 5; Treatment dose: 1,240 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,034 days (2.8 years); Days to treatment end: 1,174 days (3.2 years); Number of cycles: 6; Treatment dose: 320 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,034 days (2.8 years); Days to treatment end: 1,174 days (3.2 years); Number of cycles: 6; Treatment dose: 47 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 76.8 years (28,041 days); Days to diagnosis: 871 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 789 days (2.2 years); Disease response: With Tumor.
- Day 871 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 871 days (2.4 years); Evidence of recurrence type: Positive Biomarker(s).
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-20-0990-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-20-0990-01A-01-BS1: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 80; Percent normal cells: 18; Percent necrosis: 2; Percent stromal cells: 2.
  Slide TCGA-20-0990-01A-01-TS1: Section location: Top; Percent tumor cells: 91; Percent tumor nuclei: 95; Percent normal cells: 6; Percent necrosis: 2; Percent stromal cells: 1.
- Sample TCGA-20-0990-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Fine needle aspiration biopsy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Liposomal Doxorubican.
- Drug treatment 4: Pharmaceutical therapy drug name: Paclitaxil.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-20-0990-01): tumor purity 0.88, ploidy 3, whole-genome doublings 1 (call status: legacy_call).
